Surgical pathology report (de-identified scan), TCGA case TCGA-CG-4440, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Indivumed, specimen TCGA-CG-4440-01A (Primary Tumor).

Diagnosis/diagnoses:

2.: Total gastrectomy preparation with part of transverse colon attached. Stomach with an ulcerated gastric carcinoma located in the middle of the stomach on the side of the greater curvature, extending to within 5 cm of the aboral and 7 cm of the oral resection margin, encroaching on the anterior and posterior wall of the stomach, with a maximum diameter of 7 cm and characterized histologically as a poorly differentiated adenocarcinoma (gastric carcinoma of the intestinal type). Invasive tumor spread within all the parietal layers of the stomach extending deep into the perigastric fatty tissue and up to 4 cm into the gastrocolic ligament and as far as the serosa with penetration of the serosa. In the tumor resection region are branches of carcinomatous lymphangitis and small nodular carcinosis of the gastric serosa. Oral and aboral resection margin, greater omentum and transverse colon part tumor-free. Eighteen of twenty-four lymph nodes with gastric carcinoma metastases growing over the capsule.

Mucosa of the antrum with barely florid, medium-grade chronic gastritis, foveolar hyperplasia, extensive foci of intestinal metaplasia and partial atrophy of the mucosa and also corpus mucosa with moderately florid and chronic gastritis predominantly of the superficial type with evidence of *Helicobacter pylori*.

Tumor stage thus pT3 pM1 () pN3 (18/24)

Source: NCI Genomic Data Commons file 5f4954e8-1ef8-471c-a498-97b0c4f5ac74 (TCGA-CG-4440.C3991B30-6032-4280-A791-788AC0870E0C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).